TARGET case TARGET-30-PAPUWY — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Adrenal gland. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/95d7372e-2734-5068-8f7d-7597d92c1737

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 5 years; Vital status: Dead; Days to death: 1,102 days (3.0 years).

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C74.9; Tissue or organ of origin: Adrenal gland, NOS; Classification of tumor: primary; Age at diagnosis: 5.4 years (1,955 days); Year of diagnosis: 2006; Days to last follow up: 1,102 days (3.0 years); Cog neuroblastoma risk group: High Risk; Inpc grade: Undifferentiated or Poorly Differentiated; INSS stage: Stage 4; Mitosis karyorrhexis index: High.
   Pathology details: Necrosis percent: 10; Percent tumor nuclei: 40.
   Treatment given: Protocol identifier: ANBL0621.
   Treatment given: Protocol identifier: ANBL00B1.

Follow-up (5 entries)
- Days to follow up: 765 days (2.1 years); Progression or recurrence anatomic site: Bone, NOS; Days to first event: 765 days (2.1 years); First event: Relapse.
- Days to follow up: 765 days (2.1 years); Progression or recurrence anatomic site: Lymph nodes of head, face and neck.
- Days to follow up: 765 days (2.1 years); Progression or recurrence anatomic site: Head, face or neck, NOS.
- Days to follow up: 765 days (2.1 years); Progression or recurrence anatomic site: Intrathoracic lymph nodes.
- Days to follow up: 1,102 days (3.0 years); Year of follow up: 2009.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.
- Test: Normal; Ploidy: Diploid.

Biospecimens (2 samples)
- Sample TARGET-30-PAPUWY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PAPUWY-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 1102
- Protocol: ANBL00B1, ANBL0621
- Ploidy: Diploid (DI=1)
- Ploidy Value: 1
- Histology: Unfavorable
- ICDO Description: Adrenal gland, NOS Suprarenal gland Adrenal, NOS
- Percent Tumor v/s Stroma: 40/60
- Site of Relapse: Bone; Other Metastatic Sites; Other, specify: Left supraclavicular region with hilar, pretracheal, and subcarinal lymph nodes.
